Somatic mutation profile of tumor specimen TCGA-44-2662-01A (aliquot TCGA-44-2662-01A-01D-0969-08) from TCGA case TCGA-44-2662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.7 years (24,014 days).
Specimen TCGA-44-2662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a49b1fd-2b78-4c15-ba62-42b0d2258e23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2662-10A (Blood Derived Normal), aliquot TCGA-44-2662-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3405656-8b22-41e2-b049-f4837c2f0edc

The open-access MAF lists 230 somatic variants for this specimen: 170 protein-altering or splice-affecting, 58 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 58, Nonsense Mutation 8, Splice Region 4, Splice Site 4, Frame Shift Del 3, RNA 2, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.882C>T p.L294= | Splice Region (SNP) | VAF 31/149 reads (21%) | catalogued as rs63751707, CS086119, COSV51615064; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 19/74 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.340A>T p.N114Y | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV55951076; called by muse, mutect2, varscan2
- ABCA13 | c.9493G>C p.D3165H | Missense Mutation (SNP) | VAF 47/449 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV71284199; called by muse, mutect2, varscan2
- ABCA13 | c.14104G>A p.E4702K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV68944021; called by muse, mutect2, varscan2
- ACTN2 | c.1347C>G p.S449R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100857132, COSV63972620; called by muse, mutect2, varscan2
- ALG3 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546890576, COSV56610384; called by muse, mutect2, varscan2
- AMN | c.163-1G>A p.X55_splice | Splice Site (SNP) | VAF 51/229 reads (22%) | catalogued as COSV54486203; called by muse, mutect2, varscan2
- AP4B1 | c.1775C>A p.S592* | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | catalogued as COSV56723643, COSV56724960; called by muse, mutect2, varscan2
- ATP11C | c.2737A>T p.M913L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59560166; called by muse, mutect2, varscan2
- BAX | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV53169282; called by muse, mutect2, varscan2
- BCAS3 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as rs771698366, COSV66770605; called by muse, mutect2, varscan2
- BCHE | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52254138; called by muse, mutect2, varscan2
- BMERB1 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 49/291 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV55506397; called by muse, mutect2, varscan2
- BMP2K | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs780640612, COSV58592648; called by muse, mutect2, varscan2
- C12orf56 | c.1270G>C p.E424Q (on ENST00000543942 / NM_001170633.2; = p.E264Q on NM_001099676.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61485568, COSV61488362; called by muse, mutect2, varscan2
- C1orf87 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV64596255; called by muse, mutect2, varscan2
- C2orf78 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.127); catalogued as rs1409069598, COSV68516575; called by muse, mutect2, varscan2
- CACNA1B | c.3173C>T p.A1058V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV53116343; called by muse, mutect2, varscan2
- CACNA1E | c.508A>G p.S170G | Missense Mutation (SNP) | VAF 53/282 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV62384201; called by muse, mutect2, varscan2
- CCDC146 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV53544797; called by muse, mutect2, varscan2
- CCDC88A | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55057407; called by muse, mutect2, varscan2
- CCDC90B | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52623501; called by muse, mutect2, varscan2
- CCP110 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66816618; called by muse, mutect2
- CETN3 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 20/126 reads (16%) | catalogued as COSV51616945; called by muse, mutect2, varscan2
- CHAMP1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 118/518 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs1555379780, COSV63521883; called by muse, mutect2, varscan2
- CHRNA4 | c.735C>A p.F245L | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64718614; called by muse, mutect2, varscan2
- CNTLN | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV52068519; called by muse, mutect2, varscan2
- COBL | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV54339839; called by muse, mutect2, varscan2
- CSMD3 | c.10640G>T p.S3547I (on ENST00000297405 / NM_001363185.1; = p.S3378I on NM_052900.3) | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV52116090; called by muse, mutect2
- CYFIP2 | c.2231G>T p.S744I (on ENST00000616178 / NM_001291722.2; = p.S719I on NM_014376.4) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59029806; called by muse, mutect2, varscan2
- DENND1B | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52461557; called by muse, mutect2, varscan2
- DHRS9 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs748041645, COSV59139004; called by muse, mutect2, varscan2
- DKK2 | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV53394673; called by muse, mutect2, varscan2
- DNAH10 | c.4962C>G p.I1654M (on ENST00000409039; = p.I1593M on NM_207437.3) | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV68989065, COSV68995673; called by muse, mutect2, varscan2
- DNAJC1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV65409444; called by muse, mutect2, varscan2
- DNAJC13 | c.2627C>A p.A876D | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53446612; called by muse, mutect2
- DNAJC14 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV54477846; called by muse, mutect2, varscan2
- DPY19L4 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs1385399777, COSV68962348; called by muse, mutect2, varscan2
- EML2 | c.1728C>G p.I576M | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV55597868; called by muse, mutect2
- EPAS1 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376653305; called by muse, mutect2, varscan2
- ERI3 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV64830371; called by muse, mutect2
- EXOG | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55062785; called by muse, mutect2, varscan2
- FIZ1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs1471901175, COSV55607217, COSV99684747; called by muse, mutect2, varscan2
- FLCN | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 87/400 reads (22%) | catalogued as COSV53257576; called by muse, mutect2, varscan2
- FMN2 | c.4759T>G p.L1587V | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100144541, COSV60419697; called by muse, mutect2
- FRMD8 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 105/329 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs759320847, COSV53683382; called by muse, mutect2, varscan2
- FSIP2 | c.16905G>C p.K5635N | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100554337; called by muse, mutect2
- GDAP2 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV65611979; called by muse, mutect2, varscan2
- GOLGA4 | c.6639G>T p.L2213F | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100728697; called by muse, mutect2, varscan2
- GOLGA4 | c.6640G>T p.E2214* | Nonsense Mutation (SNP) | VAF 22/139 reads (16%) | catalogued as COSV100728700; called by muse, mutect2, varscan2
- GPATCH1 | c.210A>G p.G70= | Splice Region (SNP) | VAF 12/193 reads (6%) | catalogued as rs1481598464, COSV50111744; called by muse, mutect2
- GPATCH1 | c.1389G>T p.R463S | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV50111020, COSV50111767, COSV50112587; called by muse, mutect2, varscan2
- GPBP1L1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV51967299; called by muse, mutect2
- GSDMC | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as rs910419404, COSV52692967; called by muse, mutect2, varscan2
- GSDMD | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV52796493; called by muse, mutect2, varscan2
- GSDME | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as COSV61651075; called by muse, mutect2
- GTF2I | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs145729076; called by muse, mutect2
- GUCY1A2 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); catalogued as COSV56479596; called by muse, mutect2
- HCN1 | c.1708A>T p.N570Y | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV57496403; called by muse, mutect2
- IL1RAPL1 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56234164, COSV56241733; called by muse, mutect2, varscan2
- IMPG2 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV51974431; called by muse, mutect2, varscan2
- INTS11 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.378); catalogued as rs1246401538, COSV60087563; called by muse, mutect2, varscan2
- JAKMIP2 | c.2179C>G p.L727V | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV54598719; called by muse, mutect2, varscan2
- KIF15 | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); catalogued as COSV100392470, COSV58158904; called by muse, mutect2
- KIF26B | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs375797576; called by muse, mutect2, varscan2
- KIN | c.479A>T p.K160M | Missense Mutation (SNP) | VAF 35/316 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65430057; called by muse, mutect2, varscan2
- KLHL15 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60139363; called by muse, mutect2, varscan2
- KLHL3 | c.1578C>A p.C526* | Nonsense Mutation (SNP) | VAF 65/339 reads (19%) | catalogued as COSV59051273, COSV59054767; called by muse, mutect2, varscan2
- KNDC1 | c.4697C>G p.S1566C | Missense Mutation (SNP) | VAF 97/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs757639617, COSV58832188, COSV58841310; called by muse, mutect2, varscan2
- KRTAP23-1 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV61935551; called by muse, mutect2
- LCAT | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50452188; called by muse, mutect2, varscan2
- LGALS9 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 67/353 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56348151; called by muse, mutect2, varscan2
- LGR4 | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as COSV60820240; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.266); catalogued as COSV53275994, COSV53278487; called by muse, mutect2
- LRRC4C | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs775124868, COSV53419365; called by muse, mutect2, varscan2
- LRRC75B | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs774666585, COSV50638326, COSV50639134; called by muse, mutect2, varscan2
- LYN | c.723G>C p.E241D | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV70205381; called by muse, mutect2
- MACF1 | c.5555C>T p.S1852L | Missense Mutation (SNP) | VAF 36/199 reads (18%) | catalogued as COSV57109524; called by muse, mutect2, varscan2
- MAIP1 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.741); catalogued as COSV54460280; called by muse, mutect2, varscan2
- MAP3K13 | c.1170-1G>A p.X390_splice | Splice Site (SNP) | VAF 30/116 reads (26%) | catalogued as COSV53984357; called by muse, mutect2
- MCTP1 | c.1515G>C p.K505N | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV56505994; called by muse, mutect2, varscan2
- MGAT3 | c.627C>G p.I209M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57864285; called by mutect2, varscan2
- MMUT | c.532C>G p.P178A | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV51272443; called by muse, mutect2, varscan2
- MTBP | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59961276, COSV59961624; called by muse, mutect2, varscan2
- MUC16 | c.18502G>C p.G6168R | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as COSV67449722, COSV67478144; called by muse, mutect2, varscan2
- MYCBP2 | c.4337G>C p.G1446A (on ENST00000357337; = p.G1484A on NM_015057.5) | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV62011668; called by muse, mutect2, varscan2
- MYLK2 | c.1409T>C p.V470A | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65658665; called by muse, mutect2, varscan2
- MYMK | c.444C>A p.S148R | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.482); catalogued as COSV60599989, COSV60600171; called by muse, mutect2, varscan2
- N4BP1 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV52209788; called by muse, mutect2
- NCKAP1L | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV53204058; called by muse, mutect2, varscan2
- NIPAL4 | c.1206C>G p.F402L | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV57423918, COSV57430406; called by muse, mutect2, varscan2
- NLRP13 | c.1348C>G p.Q450E | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV100738131, COSV61620365; called by muse, mutect2, varscan2
- NOP16 | c.393G>A p.K131= | Splice Region (SNP) | VAF 27/191 reads (14%) | catalogued as COSV51257452; called by muse, mutect2, varscan2
- NPPA | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.049); catalogued as COSV56738360; called by muse, mutect2
- NUMB | c.981C>G p.I327M (on ENST00000355058; = p.I316M on NM_003744.5) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61828178, COSV61830428; called by muse, mutect2, varscan2
- OBSL1 | c.1776C>G p.I592M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV54712574; called by muse, mutect2
- OLFM4 | c.1275G>T p.Q425H | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54576084; called by muse, mutect2, varscan2
- OPLAH | c.3823C>T p.H1275Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV66298192; called by muse, mutect2, varscan2
- OR10X1 | c.124T>A p.F42I | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV63767025; called by muse, mutect2, varscan2
- OR2L8 | c.513G>T p.R171S | Missense Mutation (SNP) | VAF 59/300 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61725780, COSV61728604; called by muse, mutect2, varscan2
- OR2M4 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV60707445; called by muse, mutect2, varscan2
- OR7A5 | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV59234224; called by muse, mutect2, varscan2
- OR8G5 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as COSV100422267; called by muse, mutect2
- PCDHA8 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs146582216, COSV65323904; called by muse, mutect2
- PDGFRB | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55801742; called by muse, mutect2, varscan2
- PEX14 | c.73C>G p.R25G | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63059929, COSV63060006; called by muse, mutect2, varscan2
- PHKB | c.2737G>C p.D913H | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV54515846; called by muse, mutect2, varscan2
- PIGX | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56359154; called by muse, mutect2, varscan2
- PKHD1L1 | c.7663G>A p.D2555N | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV65737711; called by muse, mutect2, varscan2
- PLCL1 | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV70822292; called by muse, mutect2
- PLD5 | c.1202C>A p.A401E (on ENST00000442594; = p.A339E on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV59135609; called by muse, mutect2, varscan2
- PLP1 | c.699C>T p.F233= | Splice Region (SNP) | VAF 35/96 reads (36%) | catalogued as COSV58275720; called by muse, mutect2, varscan2
- PPP2R2A | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV60095931; called by muse, mutect2, varscan2
- PPP6R3 | c.2493A>C p.K831N (on ENST00000393800 / NM_001352375.2; = p.K751N on NM_018312.5) | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as COSV55722277; called by muse, mutect2, varscan2
- PREPL | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.938); catalogued as COSV53215383; called by muse, mutect2, varscan2
- PTPRZ1 | c.5657C>G p.P1886R | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV66431672; called by muse, mutect2, varscan2
- PURB | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770929116, COSV67480166; called by mutect2, varscan2
- RIF1 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV54613278; called by muse, mutect2, varscan2
- RPL11 | c.296C>T p.S99L (on ENST00000374550 / NM_001199802.1; = p.S100L on NM_000975.5) | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs11556036, COSV65778420; called by muse, mutect2, varscan2
- RPL22 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52377101; called by muse, mutect2
- RTEL1 | c.2033C>G p.S678C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV58891288, COSV58901671; called by muse, mutect2
- RUFY1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60158676; called by muse, mutect2
- RYR1 | c.11362G>C p.E3788Q | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV62090965, COSV62091055; called by muse, mutect2
- SAMD15 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV53625454; called by muse, mutect2, varscan2
- SBSN | c.1463G>T p.G488V (on ENST00000452271 / NM_001166034.2; = p.G145V on NM_198538.4) | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1408212094, COSV71733065; called by muse, mutect2, varscan2
- SEZ6L | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as COSV50658819; called by muse, mutect2
- SLC12A7 | c.343-2A>T p.X115_splice | Splice Site (SNP) | VAF 23/297 reads (8%) | catalogued as COSV53754988; called by muse, mutect2
- SLC22A8 | c.1323C>G p.I441M | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs755445118, COSV60324005; called by muse, mutect2
- SLC26A3 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs868438571, COSV60639061, COSV60640869; called by muse, mutect2
- SLC39A12 | c.1793C>G p.S598C (on ENST00000377369 / NM_001145195.2; = p.S561C on NM_152725.3) | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs765088632, COSV66195699; called by muse, mutect2
- SLCO5A1 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV52654919; called by muse, mutect2, varscan2
- SMAD4 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV61685296, COSV61696805; called by muse, mutect2, varscan2
- SMG5 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV62434193, COSV62434555; called by muse, mutect2, varscan2
- SP140 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV59446967; called by muse, mutect2
- ST6GALNAC3 | c.917G>C p.*306Sext*1 | Nonstop Mutation (SNP) | VAF 35/160 reads (22%) | catalogued as rs1259641661, COSV60322588; called by muse, mutect2, varscan2
- STAG3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 75/497 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV57928012; called by muse, mutect2, varscan2
- STAT2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs149666262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAAR9 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71512183; called by muse, mutect2
- TACC2 | c.6073G>C p.D2025H (on ENST00000334433; = p.D103H on NM_006997.4) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53277076, COSV53278918; called by muse, mutect2, varscan2
- THAP12 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as COSV52609641, COSV52611941; called by muse, mutect2, varscan2
- TLK2 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); catalogued as rs777808122, COSV58297734; called by muse, mutect2, varscan2
- TMEM108 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); catalogued as COSV58865488; called by muse, mutect2, varscan2
- TRA2A | c.35G>C p.R12T | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51715959; called by muse, mutect2, varscan2
- TRBC2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs782153350; called by muse, mutect2, varscan2
- TRHDE | c.1466T>C p.L489P | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53835267; called by muse, mutect2, varscan2
- TRIM7 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51240776; called by muse, mutect2, varscan2
- TRPM7 | c.3053G>T p.R1018I | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57914027; called by muse, mutect2, varscan2
- TSC22D2 | c.1610A>T p.Q537L | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV62622252; called by muse, mutect2, varscan2
- TSHZ3 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 21/358 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.378); catalogued as COSV53665760; called by muse, mutect2
- TTC23 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 16/71 reads (23%) | catalogued as COSV50440833; called by muse, mutect2, varscan2
- TTC8 | c.1374G>A p.M458I (on ENST00000338104 / NM_001288781.1; = p.M442I on NM_144596.4) | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as rs758330370, COSV57626554; called by muse, varscan2
- TTN | c.11507A>T p.Q3836L (on ENST00000591111; = p.Q3790L on NM_003319.4) | Missense Mutation (SNP) | VAF 58/282 reads (21%) | catalogued as COSV59914943; called by muse, mutect2, varscan2
- TYRO3 | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV55481275, COSV55487658; called by muse, mutect2, varscan2
- UBAP2 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.366); catalogued as COSV62545428, COSV62548950; called by muse, varscan2
- UNC5B | c.2063C>G p.S688C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV58974964; called by muse, mutect2, varscan2
- UQCRQ | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51525893; called by muse, mutect2, varscan2
- USP34 | c.3709C>G p.L1237V | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV68398939; called by muse, mutect2
- UVRAG | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62101812; called by muse, mutect2
- ZBBX | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV56784066; called by muse, mutect2, varscan2
- ZFHX4 | c.1163C>G p.T388S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50551279; called by muse, mutect2, varscan2
- ZNF507 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758381137, COSV61330269; called by muse, mutect2
- ZNF546 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as COSV61257303; called by muse, mutect2
- ZNF597 | c.46T>C p.F16L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV57083674, COSV57085949; called by muse, mutect2, varscan2
- AAR2 | c.431_439delinsGAG p.T144_K147delinsRE | In Frame Del (DEL) | VAF 40/268 reads (15%) | called by pindel, varscan2*
- AHNAK | c.345_357del p.S115Rfs*15 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- MFSD8 | c.1271del p.V424Gfs*2 | Frame Shift Del (DEL) | VAF 31/169 reads (18%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.1700_1704del p.S567Ffs*10 | Frame Shift Del (DEL) | VAF 37/213 reads (17%) | called by mutect2, pindel, varscan2
- PTPN20 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ABHD11 | c.846C>T p.L282= | Silent (SNP) | VAF 22/147 reads (15%) | catalogued as COSV56105325; called by muse, varscan2
- ADD3 | c.639C>T p.F213= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV53320887; called by muse, mutect2, varscan2
- AKT2 | c.627C>T p.H209= | Silent (SNP) | VAF 38/1146 reads (3%) | catalogued as COSV60907765; called by muse, mutect2
- ASNS | c.981C>T p.V327= | Silent (SNP) | VAF 19/189 reads (10%) | catalogued as rs769326809, COSV51550648; called by muse, mutect2, varscan2
- ATN1 | c.930C>G p.L310= | Silent (SNP) | VAF 23/180 reads (13%) | catalogued as COSV63110355; called by muse, mutect2, varscan2
- BCAR1 | c.2238C>T p.F746= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV50779076; called by muse, mutect2, varscan2
- CACNA1B | c.1572C>G p.L524= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV53116322; called by muse, varscan2
- CACNA1F | c.723A>T p.A241= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV59903314; called by muse, mutect2, varscan2
- CACNG4 | c.981G>T p.V327= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as COSV50924266; called by muse, mutect2, varscan2
- CCDC87 | c.2034G>A p.L678= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as COSV59578490; called by muse, mutect2, varscan2
- CD59 | c.24C>G p.V8= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV60918993; called by muse, mutect2
- CNOT1 | c.3804G>A p.E1268= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs1240474585, COSV55313819; called by muse, mutect2
- CPA3 | c.441T>C p.S147= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV56043997; called by muse, mutect2, varscan2
- CSMD1 | c.7977T>C p.H2659= (on ENST00000520002; = p.H2658= on NM_033225.6) | Silent (SNP) | VAF 44/357 reads (12%) | catalogued as rs1420433528, COSV59289766; called by muse, mutect2, varscan2
- DNAH8 | c.2925G>T p.G975= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV59429556; called by muse, mutect2, varscan2
- DSTN | c.108C>T p.V36= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as COSV55712305; called by muse, mutect2, varscan2
- ELOVL5 | c.102C>T p.P34= | Silent (SNP) | VAF 14/151 reads (9%) | catalogued as rs374432575; called by muse, mutect2
- EVI5 | c.1203C>T p.V401= | Silent (SNP) | VAF 45/280 reads (16%) | catalogued as COSV64825788; called by muse, mutect2, varscan2
- FBXO41 | c.2490G>A p.G830= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as rs1185112178, COSV54582328; called by muse, mutect2, varscan2
- FXR1 | c.834C>T p.F278= | Silent (SNP) | VAF 54/230 reads (23%) | catalogued as COSV59761409; called by muse, mutect2, varscan2
- GARS1 | c.1371G>A p.E457= | Silent (SNP) | VAF 49/290 reads (17%) | catalogued as COSV66827960; called by muse, mutect2, varscan2
- GC | c.138C>A p.V46= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV56735678, COSV99909497; called by muse, mutect2, varscan2
- GPR183 | c.969G>C p.L323= | Silent (SNP) | VAF 27/164 reads (16%) | catalogued as COSV63117180; called by muse, mutect2, varscan2
- GPR27 | c.903C>T p.V301= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV55203106; called by muse, mutect2, varscan2
- GRK6 | c.381G>C p.T127= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV62681917; called by mutect2, varscan2
- GRK6 | c.1458C>T p.V486= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as COSV62681920; called by muse, mutect2, varscan2
- HYI | c.765C>T p.F255= (on ENST00000372434 / NM_001330526.2; = p.F230= on NM_031207.6) | Silent (SNP) | VAF 40/176 reads (23%) | catalogued as COSV65094217; called by muse, mutect2, varscan2
- IGSF22 | c.1680G>A p.Q560= | Silent (SNP) | VAF 26/180 reads (14%) | catalogued as COSV60031515; called by muse, mutect2, varscan2
- KLKB1 | c.45T>A p.A15= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV52994258; called by muse, mutect2, varscan2
- LNPEP | c.2277G>A p.E759= | Silent (SNP) | VAF 37/225 reads (16%) | catalogued as COSV51476664; called by muse, mutect2, varscan2
- LRP1 | c.3468C>T p.T1156= | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as rs1347019663, COSV54503612; called by muse, mutect2, varscan2
- MAST3 | c.2781G>T p.S927= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV53218022; called by muse, mutect2, varscan2
- MED12 | c.4134C>G p.L1378= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV61333791; called by muse, mutect2, varscan2
- MED12 | c.4293C>A p.L1431= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV61333804; called by muse, mutect2, varscan2
- MOCS3 | c.600C>T p.L200= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV54865742; called by muse, varscan2
- MYCBP2 | c.4287G>C p.L1429= (on ENST00000357337; = p.L1467= on NM_015057.5) | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs377177103, COSV62011678; called by muse, mutect2, varscan2
- OR1C1 | c.867C>A p.I289= | Silent (SNP) | VAF 26/181 reads (14%) | catalogued as COSV68715457; called by muse, mutect2, varscan2
- PCLO | c.2988G>A p.V996= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV61619415; called by muse, mutect2, varscan2
- PCMTD2 | c.564C>T p.V188= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV55059281; called by muse, mutect2, varscan2
- PDPR | c.2310C>T p.F770= | Silent (SNP) | VAF 63/336 reads (19%) | catalogued as COSV55349631; called by muse, mutect2, varscan2
- PIDD1 | c.2013C>T p.A671= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as rs1298388062, COSV57192425; called by muse, mutect2, varscan2
- PKHD1 | c.5166C>T p.I1722= | Silent (SNP) | VAF 15/176 reads (9%) | catalogued as COSV61863471; called by muse, mutect2
- PNPLA7 | c.150C>T p.F50= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs1052637819, COSV52995085; called by muse, mutect2, varscan2
- POLK | c.1197C>T p.S399= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as COSV54032674; called by muse, mutect2
- POT1 | c.375C>T p.F125= | Silent (SNP) | VAF 82/282 reads (29%) | catalogued as COSV62928375; called by muse, mutect2, varscan2
- PSD3 | c.2758C>T p.L920= (on ENST00000440756; = p.L919= on NM_015310.4) | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs377209838, COSV54067396; called by muse, mutect2, varscan2
- PTBP3 | c.567C>G p.L189= | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as COSV52956154; called by muse, mutect2, varscan2
- SLC35B2 | c.1221C>G p.L407= | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as COSV51487931; called by muse, mutect2, varscan2
- SLC38A11 | c.951C>A p.L317= (on ENST00000409149 / NM_001351539.1; = p.L295= on NM_173512.2) | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV58052069; called by muse, mutect2
- SULT1B1 | c.730C>T p.L244= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as rs777807938, COSV60206775; called by muse, mutect2, varscan2
- SZT2 | c.3717C>T p.V1239= (on ENST00000634258 / NM_001365999.1; = p.V1182= on NM_015284.4) | Silent (SNP) | VAF 20/179 reads (11%) | catalogued as COSV65167756; called by muse, mutect2, varscan2
- TENM1 | c.708C>A p.T236= | Silent (SNP) | VAF 41/247 reads (17%) | catalogued as COSV64426331; called by muse, mutect2, varscan2
- TEX264 | c.360C>T p.F120= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV58133614; called by muse, mutect2
- TRRAP | c.723G>A p.L241= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as COSV62840348, COSV62848788; called by muse, mutect2, varscan2
- ULBP3 | c.684C>G p.L228= | Silent (SNP) | VAF 17/169 reads (10%) | catalogued as COSV66253992; called by muse, mutect2, varscan2
- UTRN | c.8820C>G p.L2940= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV62307722; called by muse, mutect2, varscan2
- ZFHX3 | c.10881G>A p.A3627= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs892312481, COSV51710753; called by muse, mutect2, varscan2
- ZFPM2 | c.969G>A p.V323= | Silent (SNP) | VAF 53/263 reads (20%) | catalogued as COSV65872748; called by muse, mutect2, varscan2
- OR2W5 | n.1042C>A | RNA (SNP) | VAF 47/312 reads (15%) | called by muse, mutect2, varscan2
- SNORD115-3 | n.1G>A | RNA (SNP) | VAF 70/364 reads (19%) | catalogued as rs761103960; called by muse, mutect2, varscan2
